Somatic mutation profile of tumor specimen TCGA-B0-5098-01A (aliquot TCGA-B0-5098-01A-01D-1421-08) from TCGA case TCGA-B0-5098, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 53.7 years (19,620 days).
Specimen TCGA-B0-5098-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac7342c0-fc68-4d07-a420-f32c1055c419.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5098-11A (Solid Tissue Normal), aliquot TCGA-B0-5098-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2849a716-3cde-42be-8903-ce657101fb1d

The open-access MAF lists 716 somatic variants for this specimen: 560 protein-altering or splice-affecting, 142 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 381, Silent 142, Frame Shift Del 95, Splice Site 23, Nonsense Mutation 22, Frame Shift Ins 21, In Frame Del 10, Intron 7, Splice Region 6, 3'UTR 3, 5'Flank 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALX4 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 131/413 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs104894193, CM010011, COSV61326325; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1265del p.K422Sfs*10 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs397508083; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 24/91 reads (26%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.96184C>T p.R32062* (on ENST00000591111; = p.R24638* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 35/114 reads (31%) | catalogued as rs766265889, COSV60293903; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.1757T>C p.I586T | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV65317531; called by muse, mutect2, varscan2
- ABL2 | c.734T>C p.V245A (on ENST00000502732 / NM_007314.4; = p.V230A on NM_005158.5) | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61013575, COSV61019863; called by muse, mutect2, varscan2
- ABLIM2 | c.1279G>A p.V427I (on ENST00000341937 / NM_001130084.2; = p.V460I on NM_001130083.2) | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.066); catalogued as rs370025292; called by muse, mutect2, varscan2
- AC013489.1 | c.1558T>C p.F520L | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51553216; called by muse, mutect2, varscan2
- ACSL1 | c.672A>G p.I224M | Missense Mutation (SNP) | VAF 67/117 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.626); catalogued as COSV55665996; called by muse, mutect2, varscan2
- ACVR1 | c.643+2T>C p.X215_splice | Splice Site (SNP) | VAF 39/120 reads (33%) | catalogued as COSV55118605, COSV55122229; called by muse, mutect2, varscan2
- ADAD2 | c.1601T>C p.V534A (on ENST00000315906 / NM_001145400.2; = p.V616A on NM_139174.4) | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1278702392, COSV51894933; called by muse, mutect2, varscan2
- ADAMTS18 | c.2690A>G p.K897R | Missense Mutation (SNP) | VAF 88/249 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.068); catalogued as rs762815250, COSV51422003; called by muse, varscan2
- ADAMTS20 | c.3067C>T p.P1023S | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV67137939; called by muse, mutect2, varscan2
- ADCY5 | c.1999A>G p.I667V | Missense Mutation (SNP) | VAF 106/337 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV59203368; called by muse, mutect2, varscan2
- ADCY7 | c.907G>C p.V303L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV54270256; called by muse, varscan2
- ADGRB3 | c.2717T>A p.I906K | Missense Mutation (SNP) | VAF 133/371 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53257662; called by muse, mutect2, varscan2
- ADGRD1 | c.475T>C p.S159P | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV55455079; called by muse, mutect2, varscan2
- ADGRG4 | c.5890A>G p.I1964V | Missense Mutation (SNP) | VAF 98/175 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs181533402, COSV54964965; called by muse, mutect2, varscan2
- AEBP1 | c.1280A>G p.D427G | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56260764; called by muse, mutect2, varscan2
- AEBP1 | c.3175A>G p.T1059A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1156373127, COSV56260774; called by muse, mutect2, varscan2
- AHCTF1 | c.3994A>G p.S1332G (on ENST00000366508; = p.S1306G on NM_015446.5) | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1017200352, COSV58254259; called by muse, mutect2, varscan2
- AHNAK2 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as COSV60927946; called by muse, mutect2, varscan2
- AJUBA | c.1128G>T p.K376N | Missense Mutation (SNP) | VAF 170/243 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52986510; called by muse, mutect2, varscan2
- AMBP | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs780641166, COSV99469380; called by muse, mutect2
- AMOTL2 | c.818del p.P273Lfs*13 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as rs1319526303; called by mutect2, pindel, varscan2
- ANK3 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55077928; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3860del p.P1287Lfs*10 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | catalogued as COSV51847039; called by mutect2, pindel, varscan2
- ANKRD26 | c.2380A>G p.S794G | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV101063423; called by muse, mutect2, varscan2
- ANKRD30A | c.1708A>G p.S570G (on ENST00000611781; = p.S514G on NM_052997.2) | Missense Mutation (SNP) | VAF 48/466 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.176); catalogued as rs1261114138, COSV64618983; called by muse, varscan2
- ANXA6 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV62908010; called by muse, mutect2, varscan2
- AP1G1 | c.2428C>A p.L810I | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs766353180, COSV55494469; called by muse, mutect2, varscan2
- ARHGAP18 | c.967dup p.C323Lfs*32 | Frame Shift Ins (INS) | VAF 26/105 reads (25%) | catalogued as rs1292136331; called by mutect2, pindel, varscan2
- ARHGEF1 | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1555849687, COSV61529398; called by muse, mutect2
- ARHGEF7 | c.1921C>A p.L641M (on ENST00000375741 / NM_001113511.2; = p.L463M on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54550137; called by muse, mutect2, varscan2
- ARSG | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.636); catalogued as rs781372500, COSV71593895; called by muse, mutect2, varscan2
- ASB13 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.376); catalogued as rs1475210721, COSV63092033; called by muse, mutect2, varscan2
- ATAD2B | c.4226T>C p.V1409A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53204261; called by muse, mutect2
- ATF7IP | c.2941+2T>C p.X981_splice | Splice Site (SNP) | VAF 31/88 reads (35%) | catalogued as COSV53770815, COSV53776429; called by muse, mutect2, varscan2
- ATG4A | c.795T>G p.Y265* | Nonsense Mutation (SNP) | VAF 123/231 reads (53%) | catalogued as COSV58967252, COSV58967744; called by muse, mutect2, varscan2
- ATP1B4 | c.664T>G p.F222V (on ENST00000218008 / NM_001142447.3; = p.F218V on NM_012069.5) | Missense Mutation (SNP) | VAF 129/239 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54314687; called by muse, mutect2, varscan2
- ATP2C2 | c.2675T>C p.I892T | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs779302905, COSV52300562; called by muse, mutect2, varscan2
- ATP4A | c.1760T>C p.M587T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.796); catalogued as COSV52871280; called by muse, mutect2, varscan2
- ATP6AP1 | c.839A>G p.D280G | Missense Mutation (SNP) | VAF 88/142 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63896214; called by muse, varscan2
- ATP6V1B1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV52270191; called by muse, mutect2, varscan2
- ATXN1 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55228797; called by muse, mutect2, varscan2
- BAG1 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs774927813, COSV56302471; called by muse, mutect2, varscan2
- BAG6 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 117/290 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV52994422; called by muse, mutect2, varscan2
- BAHCC1 | c.1352A>T p.E451V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV57032464; called by muse, mutect2
- BAZ2B | c.963G>T p.Q321H | Missense Mutation (SNP) | VAF 85/293 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.28); catalogued as COSV58608586; called by muse, mutect2, varscan2
- BCL9 | c.2726dup p.V910Cfs*42 | Frame Shift Ins (INS) | VAF 40/76 reads (53%) | catalogued as rs1553205212; called by mutect2, varscan2
- BCORL1 | c.4496A>G p.N1499S | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV54405069; called by muse, mutect2, varscan2
- BET1L | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57316132; called by muse, mutect2, varscan2
- BMP4 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.2); catalogued as rs773506129, COSV55417096; called by muse, mutect2, varscan2
- BSCL2 | c.329T>C p.L110S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54017583; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C1orf122 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV65990327; called by muse, mutect2, varscan2
- C20orf194 | c.2884A>G p.K962E | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.488); catalogued as COSV52701724; called by muse, mutect2, varscan2
- C20orf204 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs1426630195, COSV53874023; called by muse, mutect2, varscan2
- C4BPA | c.851A>G p.D284G | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.35); catalogued as COSV65537374; called by muse, varscan2
- CACNA1F | c.3443A>G p.Y1148C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59906617; called by muse, mutect2
- CAMKK1 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.398); catalogued as COSV50124380; called by muse, mutect2, varscan2
- CAMSAP3 | c.2428C>A p.L810M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV50353177; called by muse, mutect2, varscan2
- CASS4 | c.1149G>A p.W383* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | catalogued as rs895670548, COSV64388146; called by muse, mutect2, varscan2
- CCDC54 | c.456A>G p.I152M | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV53759729; called by muse, mutect2, varscan2
- CCDC88B | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57267836; called by muse, mutect2, varscan2
- CCDC91 | c.545T>C p.I182T | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV60347635; called by muse, mutect2, varscan2
- CCT8 | c.613T>C p.C205R | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1411808332, COSV54505881; called by muse, varscan2
- CD1B | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1394701046, COSV63804410, COSV63805060; called by muse, mutect2, varscan2
- CDC42BPG | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777210451, COSV61348924; called by muse, mutect2, varscan2
- CDK12 | c.1046+2T>C p.X349_splice | Splice Site (SNP) | VAF 27/94 reads (29%) | catalogued as COSV71002609; called by muse, mutect2, varscan2
- CELSR2 | c.4862G>A p.G1621D | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1446362517, COSV54778447; called by muse, mutect2, varscan2
- CEP152 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs201569877; called by muse, varscan2
- CERT1 | c.677G>A p.R226H (on ENST00000405807 / NM_001130105.1; = p.R98H on NM_005713.3) | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278875299, COSV54663687; called by muse, mutect2, varscan2
- CES1 | c.415A>T p.I139F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62089712; called by muse, mutect2, varscan2
- CHD4 | c.529A>G p.N177D | Missense Mutation (SNP) | VAF 276/777 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58909162; called by muse, mutect2, varscan2
- CHD5 | c.992G>T p.R331M | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV52423286; called by muse, mutect2, varscan2
- CHD6 | c.3188A>G p.D1063G | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV58561560; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | catalogued as rs751548647; called by mutect2, varscan2
- CLCN3 | c.1663T>C p.W555R | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.435); catalogued as COSV61628309; called by muse, mutect2, varscan2
- CLIP3 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs748488607, COSV53325637; called by muse, mutect2, varscan2
- CNN2 | c.700A>G p.K234E | Missense Mutation (SNP) | VAF 110/208 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV54036241; called by muse, mutect2, varscan2
- CNPY4 | c.41dup p.L14Ffs*17 | Frame Shift Ins (INS) | VAF 28/100 reads (28%) | catalogued as rs1347948509; called by mutect2, varscan2
- CNST | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as COSV63622336; called by muse, mutect2, varscan2
- COG2 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs201839796, COSV64188101; called by muse, mutect2, varscan2
- COL14A1 | c.984G>C p.E328D | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.017); catalogued as COSV52865961; called by muse, mutect2, varscan2
- COL6A2 | c.587T>C p.L196P | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV56014601; called by muse, mutect2, varscan2
- CORO2B | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 98/323 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55956661; called by muse, mutect2, varscan2
- CPEB4 | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 116/338 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as rs1411346660, COSV54175497; called by muse, mutect2, varscan2
- CRHR2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as rs762243978, COSV100529808, COSV59267598; called by muse, mutect2, varscan2
- CRYM | c.872A>G p.K291R | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54832875; called by muse, mutect2, varscan2
- CSGALNACT1 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs1173229620, COSV59982435; called by muse, mutect2, varscan2
- CTAGE1 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV66944523; called by muse, mutect2, varscan2
- CUBN | c.581T>C p.M194T | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.036); catalogued as COSV64701891; called by muse, mutect2
- DCAF17 | c.1231del p.S411Vfs*23 | Frame Shift Del (DEL) | VAF 50/127 reads (39%) | catalogued as rs755674655; called by mutect2, varscan2
- DCST2 | c.1643T>C p.L548P | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55054138; called by muse, mutect2
- DDA1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs750336329, COSV50178890; called by muse, mutect2, varscan2
- DENND4A | c.4600G>A p.A1534T | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV71266880; called by muse, mutect2
- DEPDC5 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs12158711, COSV56708389; called by muse, mutect2, varscan2
- DHRS4 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 62/103 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs753447935, COSV100366028; called by muse, mutect2, varscan2
- DHRS4 | c.182T>G p.V61G | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100366032; called by muse, mutect2, varscan2
- DHX32 | c.685_687del p.Y229del | In Frame Del (DEL) | VAF 44/344 reads (13%) | catalogued as rs1370610503; called by pindel, varscan2
- DHX37 | c.386A>C p.K129T | Missense Mutation (SNP) | VAF 189/565 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV58138834; called by muse, mutect2, varscan2
- DIS3 | c.1921A>G p.M641V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1406515508, COSV66707760; called by muse, mutect2, varscan2
- DIS3L | c.2201+2T>C p.X734_splice (on ENST00000319212 / NM_001143688.3; = p.X651_splice on NM_133375.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 34/108 reads (31%) | catalogued as COSV100055618, COSV59913449; called by muse, mutect2, varscan2
- DIS3L2 | c.1970G>T p.R657L | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV56061922; called by muse, mutect2, varscan2
- DLC1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 43/514 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.033); catalogued as rs757341482, COSV52324131; called by muse, mutect2
- DNAH2 | c.11835G>A p.M3945I | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV66725478; called by muse, mutect2
- DNAH9 | c.2087T>G p.F696C | Missense Mutation (SNP) | VAF 150/380 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52372369; called by muse, mutect2, varscan2
- DNAJB2 | c.955T>C p.S319P | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.093); catalogued as COSV55351639; called by muse, varscan2
- DPAGT1 | c.497-2A>C p.X166_splice | Splice Site (SNP) | VAF 59/154 reads (38%) | catalogued as COSV62615077; called by muse, mutect2, varscan2
- DPCD | c.295A>G p.K99E | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV64509796; called by muse, mutect2, varscan2
- DPP3 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV64757855; called by muse, mutect2, varscan2
- DSG3 | c.1412-2A>G p.X471_splice | Splice Site (SNP) | VAF 83/240 reads (35%) | catalogued as COSV57129131; called by muse, mutect2, varscan2
- DTX3 | c.206del p.P69Rfs*9 | Frame Shift Del (DEL) | VAF 81/266 reads (30%) | catalogued as COSV54088851; called by mutect2, pindel, varscan2
- DYRK4 | c.1247G>T p.R416M | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV50543766; called by muse, mutect2, varscan2
- EGLN2 | c.758T>G p.I253S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58281060; called by muse, mutect2, varscan2
- ELAC2 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV62033934; called by muse, mutect2, varscan2
- ELAPOR2 | c.1975C>A p.P659T (on ENST00000450689 / NM_001142749.3; = p.P492T on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs757457556, COSV51890980; called by muse, mutect2, varscan2
- ELL2 | c.1760A>G p.Q587R | Missense Mutation (SNP) | VAF 144/479 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV52984825; called by muse, mutect2, varscan2
- ENOSF1 | c.344G>A p.C115Y (on ENST00000340116 / NM_001354066.2; = p.C67Y on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/317 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs746367017, COSV51895217; called by muse, mutect2, varscan2
- ENPP7 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.437); catalogued as rs140556423; called by muse, mutect2, varscan2
- EOGT | c.793T>G p.S265A | Missense Mutation (SNP) | VAF 109/196 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as COSV55153466; called by muse, mutect2, varscan2
- EPHA5 | c.2026A>G p.T676A | Missense Mutation (SNP) | VAF 107/193 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV56668674; called by muse, mutect2, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 66/186 reads (35%) | catalogued as rs756461692; called by mutect2, varscan2
- EPPK1 | c.6268C>T p.R2090W | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs782111553, COSV101599931, COSV73260944, COSV73262304; called by muse, mutect2
- ERAP2 | c.2666T>C p.L889S | Missense Mutation (SNP) | VAF 55/351 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV65941148; called by muse, mutect2, varscan2
- ERMP1 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs866325120, COSV53039043; called by muse, mutect2, varscan2
- ESPN | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.381); catalogued as COSV64705317; called by mutect2, varscan2
- ETV1 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV54138735, COSV54149913; called by muse, mutect2, varscan2
- EXOC6 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); catalogued as COSV53331558; called by muse, mutect2, varscan2
- EXT1 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 68/188 reads (36%) | catalogued as CM163292, COSV65484049; called by muse, mutect2, varscan2
- FAM135A | c.113C>G p.S38* | Nonsense Mutation (SNP) | VAF 49/155 reads (32%) | catalogued as COSV52057859; called by muse, mutect2, varscan2
- FAM78B | c.134A>T p.K45M | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV57981690; called by muse, mutect2, varscan2
- FAM83C | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1392677667, COSV65584191; called by muse, mutect2, varscan2
- FAT1 | c.7370T>C p.L2457P | Missense Mutation (SNP) | VAF 136/253 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV71675654; called by muse, mutect2, varscan2
- FBXL14 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 37/97 reads (38%) | catalogued as COSV59337459; called by muse, mutect2, varscan2
- FES | c.7T>C p.F3L | Missense Mutation (SNP) | VAF 99/336 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51579183; called by muse, mutect2, varscan2
- FGA | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV57396217; called by muse, mutect2
- FREM2 | c.1085C>A p.P362Q | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV54849631; called by muse, mutect2, varscan2
- FSTL4 | c.2369del p.G790Vfs*6 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs765771244; called by mutect2, pindel, varscan2
- FTSJ3 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs145334305; called by muse, mutect2, varscan2
- FZD10 | c.442A>G p.M148V | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as rs1170432200, COSV57475521; called by muse, mutect2, varscan2
- G3BP1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 59/169 reads (35%) | catalogued as rs140218237, COSV62366563; called by muse, mutect2, varscan2
- GAB4 | c.1310T>C p.L437P | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68755013; called by muse, mutect2, varscan2
- GALNT15 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 30/55 reads (55%) | catalogued as rs199640081, COSV60219380, COSV60220452; called by muse, mutect2, varscan2
- GAPDHS | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55883644; called by muse, mutect2, varscan2
- GAS2L1 | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99329719; called by muse, mutect2, varscan2
- GATAD2A | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53074971; called by muse, mutect2, varscan2
- GCN1 | c.2290G>C p.A764P | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.729); catalogued as COSV56113751; called by muse, mutect2, varscan2
- GEMIN5 | c.4358A>G p.K1453R | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1352648921, COSV53564197; called by muse, mutect2, varscan2
- GLO1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs371576917; called by muse, mutect2, varscan2
- GLRA1 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM1514336, COSV51008274, COSV51023572; called by muse, mutect2, varscan2
- GP1BA | c.1480dup p.T494Nfs*4 | Frame Shift Ins (INS) | VAF 40/115 reads (35%) | catalogued as rs759573909; called by mutect2, varscan2
- GPR107 | c.1707-2A>G p.X569_splice (on ENST00000372406 / NM_001136557.2; = p.X521_splice on NM_020960.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 10/21 reads (48%) | catalogued as COSV61282220; called by muse, mutect2, varscan2
- GPR180 | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV65386142; called by muse, mutect2, varscan2
- GRIN2A | c.4021del p.S1341Afs*56 | Frame Shift Del (DEL) | VAF 46/159 reads (29%) | catalogued as COSV58051797; called by mutect2, pindel, varscan2
- GRK6 | c.1652T>C p.L551P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62684105; called by muse, mutect2, varscan2
- GRM3 | c.2048T>C p.I683T | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as COSV64478432; called by muse, mutect2, varscan2
- GUCY2F | c.2939G>T p.R980L | Missense Mutation (SNP) | VAF 134/258 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761764082, COSV54306518, COSV54307430; called by muse, mutect2, varscan2
- H2AC6 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1395012854, COSV58416301; called by muse, mutect2, varscan2
- HADHA | c.1795G>A p.V599M | Missense Mutation (SNP) | VAF 130/357 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1229823387, CM040221, COSV66108512; called by muse, mutect2, varscan2
- HBE1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1267450825, COSV53081004; called by muse, mutect2
- HEATR4 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV58573308, COSV58576760; called by muse, varscan2
- HEATR5B | c.1553G>C p.C518S | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.111); catalogued as COSV51858102; called by muse, mutect2, varscan2
- HECW2 | c.3826C>A p.P1276T | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53671929; called by muse, varscan2
- HECW2 | c.2944A>G p.N982D | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.551); catalogued as COSV53671939; called by muse, mutect2, varscan2
- HHEX | c.619_621del p.E207del | In Frame Del (DEL) | VAF 48/148 reads (32%) | catalogued as rs770553856; called by pindel, varscan2
- HHIPL1 | c.1574G>A p.G525D | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.159); catalogued as COSV58092854; called by muse, mutect2, varscan2
- HOXA9 | c.757T>C p.W253R | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58656587; called by muse, mutect2, varscan2
- HOXC11 | c.358T>A p.S120T | Missense Mutation (SNP) | VAF 126/350 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as rs1379131911, COSV54533978; called by muse, varscan2
- IDH3G | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV54209714; called by muse, mutect2, varscan2
- IFNA7 | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 95/188 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99497598; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 86/280 reads (31%) | catalogued as rs760021495; called by mutect2, varscan2
- IGFBP7 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.06); catalogued as COSV55276113; called by muse, varscan2
- IGHG4 | c.660A>G p.K220= | Splice Region (SNP) | VAF 115/327 reads (35%) | catalogued as rs1410381578; called by muse, mutect2, varscan2
- IHO1 | c.740A>C p.Q247P | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56510439; called by muse, mutect2
- ILF3 | c.425A>G p.D142G | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.966); catalogued as rs1320443876, COSV51561798; called by muse, mutect2
- INPP5F | c.1715A>C p.E572A | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.918); catalogued as COSV62823373; called by muse, mutect2, varscan2
- IQCK | c.605+2T>G p.X202_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | catalogued as COSV57526751; called by mutect2, varscan2
- ISY1-RAB43 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV56442969; called by muse, mutect2
- ITGAX | c.1526T>C p.V509A | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV51644989; called by muse, mutect2
- ITIH2 | c.2694G>A p.R898= | Splice Region (SNP) | VAF 121/354 reads (34%) | catalogued as COSV64434890; called by muse, mutect2, varscan2
- ITM2C | c.538T>G p.W180G | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV58400126; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.784T>C p.S262P | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV59827829; called by muse, mutect2, varscan2
- KBTBD6 | c.1284G>T p.M428I | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.253); catalogued as COSV65271910; called by muse, mutect2, varscan2
- KCNA1 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV66838517; called by muse, mutect2, varscan2
- KCNA5 | c.1704del p.T569Pfs*15 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs1565466174, COSV99363705; called by mutect2, pindel, varscan2
- KCNN2 | c.1255-2A>G p.X419_splice (on ENST00000264773; = p.X631_splice on NM_021614.4) | Splice Site (SNP) | VAF 49/147 reads (33%) | catalogued as COSV53297477; called by muse, mutect2, varscan2
- KCNT2 | c.2595+2T>C p.X865_splice | Splice Site (SNP) | VAF 42/108 reads (39%) | catalogued as COSV54103989; called by muse, mutect2, varscan2
- KDM2A | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 170/491 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV67083717; called by muse, mutect2, varscan2
- KDM4D | c.278del p.K93Rfs*4 | Frame Shift Del (DEL) | VAF 64/168 reads (38%) | catalogued as rs142280183; called by mutect2, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 74/202 reads (37%) | catalogued as rs771545848; called by mutect2, varscan2
- KIAA0319 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.612); catalogued as rs1474891363, COSV65501702; called by muse, mutect2
- KIAA1549L | c.206A>G p.Q69R (on ENST00000321505; = p.Q366R on NM_012194.3) | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV55779924; called by muse, mutect2, varscan2
- KIAA1755 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs776317952, COSV54079923; called by muse, mutect2, varscan2
- KIF15 | c.1561A>G p.R521G | Missense Mutation (SNP) | VAF 83/144 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1156497701, COSV58162377; called by muse, mutect2, varscan2
- KIF1B | c.2482G>A p.E828K (on ENST00000377086 / NM_001365952.1; = p.E782K on NM_015074.3) | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as COSV55814993; called by muse, mutect2
- KIF24 | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 104/224 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV52661312; called by muse, mutect2, varscan2
- KIF3C | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as rs368483822; called by muse, mutect2, varscan2
- KIF5B | c.2438A>T p.K813M | Missense Mutation (SNP) | VAF 92/266 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56655781; called by muse, mutect2, varscan2
- KIRREL1 | c.1844C>A p.P615Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV63290649; called by muse, mutect2, varscan2
- KLHL7 | c.905A>G p.Q302R (on ENST00000339077 / NM_001031710.3; = p.Q254R on NM_018846.5) | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as COSV59164143; called by muse, mutect2, varscan2
- KMT2C | c.11026C>G p.L3676V | Missense Mutation (SNP) | VAF 128/320 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV51492043; called by muse, mutect2, varscan2
- KNDC1 | c.2884C>T p.Q962* | Nonsense Mutation (SNP) | VAF 35/119 reads (29%) | catalogued as COSV58844886; called by muse, mutect2, varscan2
- KPNA1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 68/463 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60271208; called by muse, mutect2, varscan2
- KPNB1 | c.2364G>A p.M788I | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV51597264, COSV51600162; called by muse, mutect2, varscan2
- KPTN | c.857T>G p.V286G | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57646180; called by muse, mutect2, varscan2
- KRR1 | c.363A>C p.K121N | Missense Mutation (SNP) | VAF 82/210 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV56992438; called by muse, mutect2, varscan2
- KRT4 | c.985C>A p.L329M | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.384); catalogued as COSV53409404; called by muse, mutect2, varscan2
- KRTAP19-2 | c.92G>T p.R31I | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as COSV61855098; called by muse, mutect2, varscan2
- KSR2 | c.554dup p.E186Gfs*200 | Frame Shift Ins (INS) | VAF 39/121 reads (32%) | catalogued as rs777127484; called by mutect2, pindel, varscan2
- LAMB1 | c.3964A>G p.T1322A | Missense Mutation (SNP) | VAF 96/262 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV55969406; called by muse, varscan2
- LENG8 | c.1472G>A p.S491N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV58729988; called by muse, mutect2, varscan2
- LPIN3 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.129); catalogued as COSV64720013; called by muse, mutect2, varscan2
- LPP | c.1646A>G p.Q549R | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs777898649, COSV57111426; called by muse, mutect2, varscan2
- LRPPRC | c.2912G>A p.W971* | Nonsense Mutation (SNP) | VAF 31/124 reads (25%) | catalogued as COSV53242451; called by muse, mutect2, varscan2
- LRPPRC | c.1822T>C p.F608L | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV53242462; called by muse, mutect2, varscan2
- LRRC27 | c.631A>G p.N211D | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV59811377; called by muse, mutect2, varscan2
- LRRIQ1 | c.4079G>T p.R1360M | Missense Mutation (SNP) | VAF 110/346 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV67837237; called by muse, mutect2, varscan2
- LUZP2 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755086981, COSV61216440; called by muse, mutect2, varscan2
- MACROH2A2 | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as rs749738000, COSV57160452; called by muse, mutect2
- MADD | c.1984C>G p.H662D | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60629131; called by muse, mutect2, varscan2
- MAP3K3 | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.09); catalogued as COSV62281596; called by muse, mutect2, varscan2
- MAP4K4 | c.3101T>A p.I1034N (on ENST00000347699 / NM_001242559.2; = p.I952N on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56339314; called by muse, mutect2
- MARK1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs767820453, COSV65070769; called by muse, mutect2, varscan2
- MAST2 | c.4331G>T p.R1444M | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV63621006; called by muse, mutect2, varscan2
- MAST4 | c.832A>T p.R278W (on ENST00000403625 / NM_001164664.2; = p.R89W on NM_015183.3) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55116162, COSV55139184; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 64/194 reads (33%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCOLN1 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 144/256 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.692); catalogued as rs1260281114, COSV51175018; called by muse, mutect2, varscan2
- MCRS1 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs746343401, COSV57792538; called by muse, mutect2, varscan2
- MCTP1 | c.1273-1G>A p.X425_splice | Splice Site (SNP) | VAF 33/103 reads (32%) | catalogued as rs748906907, COSV56530535; called by muse, mutect2, varscan2
- MED1 | c.3203C>T p.P1068L | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.254); catalogued as COSV56128059; called by muse, mutect2, varscan2
- MED12L | c.1805T>C p.L602P | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56393947; called by muse, mutect2, varscan2
- MERTK | c.1434A>G p.I478M | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV54934791; called by muse, mutect2, varscan2
- MFAP4 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs749678716, COSV55191652; called by muse, mutect2, varscan2
- MFSD8 | c.1322A>G p.Y441C | Missense Mutation (SNP) | VAF 59/100 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749153763, COSV56552809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMEL1 | c.1946A>G p.E649G | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV56525485; called by muse, mutect2, varscan2
- MOB3C | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs780307724, COSV54720218; called by muse, mutect2, varscan2
- MORC1 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs759409105, COSV51717569; called by muse, mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 12/25 reads (48%) | catalogued as rs777649506, COSV53202254; called by mutect2, pindel, varscan2
- MROH1 | c.842_844del p.F281del | In Frame Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs1329472391; called by mutect2, pindel, varscan2
- MRPL32 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs146917176; called by muse, mutect2, varscan2
- MRPS22 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as COSV60351103; called by muse, mutect2, varscan2
- MSGN1 | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55263691; called by muse, mutect2, varscan2
- MST1 | c.1919T>C p.V640A | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56536409; called by muse, mutect2, varscan2
- MTOR | c.6683T>C p.I2228T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV63877284; called by muse, mutect2, varscan2
- MTUS2 | c.1391A>G p.K464R | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV70920753; called by muse, mutect2, varscan2
- MUC17 | c.5050A>G p.T1684A | Missense Mutation (SNP) | VAF 171/500 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.304); catalogued as COSV60300808; called by muse, mutect2, varscan2
- MUC4 | c.14705del p.N4902Tfs*8 (on ENST00000463781 / NM_018406.7; = p.N666Tfs*8 on NM_004532.6) | Frame Shift Del (DEL) | VAF 77/338 reads (23%) | catalogued as rs766716021; called by mutect2, pindel, varscan2
- MXRA5 | c.6338C>T p.A2113V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV54246909; called by muse, mutect2, varscan2
- MYH10 | c.3178C>G p.L1060V | Missense Mutation (SNP) | VAF 97/267 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as COSV52609384; called by muse, mutect2, varscan2
- MYH10 | c.2368A>C p.I790L | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV52609402; called by muse, mutect2, varscan2
- MYH14 | c.2933C>T p.A978V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1175614654, COSV51829251; called by muse, mutect2, varscan2
- MYH4 | c.5266G>T p.E1756* | Nonsense Mutation (SNP) | VAF 21/307 reads (7%) | catalogued as COSV55124774; called by muse, mutect2
- MYH8 | c.4427A>G p.E1476G | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs1319472947, COSV67971154; called by muse, mutect2, varscan2
- MYL1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV58976641; called by muse, mutect2, varscan2
- MYO15A | c.8488C>T p.P2830S | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV52764202; called by muse, mutect2, varscan2
- MYO3B | c.701C>A p.P234H | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58714948; called by muse, mutect2, varscan2
- MYO6 | c.2152T>C p.Y718H | Missense Mutation (SNP) | VAF 98/289 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64120918; called by muse, mutect2, varscan2
- MYOCD | c.374dup p.N125Kfs*16 | Frame Shift Ins (INS) | VAF 62/222 reads (28%) | catalogued as rs1567587048; called by mutect2, varscan2
- MYOM1 | c.4280A>C p.E1427A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV55299971; called by muse, mutect2, varscan2
- MYOM2 | c.3741A>G p.I1247M | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV50760942; called by muse, mutect2, varscan2
- N4BP1 | c.1454C>A p.T485K | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as COSV52212877; called by muse, mutect2, varscan2
- NAA35 | c.1700del p.K567Rfs*6 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | catalogued as rs770577267; called by mutect2, varscan2
- NCOA4 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs782729934; called by muse, mutect2, varscan2
- NELL1 | c.5C>A p.P2Q | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.795); catalogued as COSV54297731, COSV54315240; called by muse, mutect2, varscan2
- NF1 | c.2567G>A p.S856N | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV62217757; called by muse, mutect2, varscan2
- NF2 | c.599+1G>A p.X200_splice | Splice Site (SNP) | VAF 35/80 reads (44%) | catalogued as CS951487, COSV100099758, COSV104404753, COSV58527473; called by muse, mutect2, varscan2
- NFASC | c.1985T>C p.V662A (on ENST00000339876 / NM_001378329.1; = p.V658A on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV58377575; called by muse, mutect2, varscan2
- NFATC1 | c.1372C>A p.H458N | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV53708014; called by muse, mutect2, varscan2
- NFATC2 | c.249dup p.G84Rfs*8 | Frame Shift Ins (INS) | VAF 18/89 reads (20%) | catalogued as rs768827421; called by mutect2, pindel, varscan2
- NGEF | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 153/483 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV50948393; called by muse, mutect2, varscan2
- NGF | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs572066909, COSV65688755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIPAL2 | c.712A>G p.M238V | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1185611048, COSV57842925; called by muse, mutect2, varscan2
- NLRC5 | c.2018C>A p.P673H | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV52661967, COSV52664416; called by muse, mutect2, varscan2
- NOC3L | c.565+2T>C p.X189_splice | Splice Site (SNP) | VAF 120/359 reads (33%) | catalogued as COSV64930515; called by muse, mutect2, varscan2
- NOP14 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 223/430 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs767174186, COSV58627456; called by muse, mutect2, varscan2
- NR1H4 | c.1398G>A p.M466I (on ENST00000551379 / NM_001206993.2; = p.M452I on NM_005123.4) | Missense Mutation (SNP) | VAF 109/309 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV51856006; called by muse, mutect2, varscan2
- NR6A1 | c.1009A>G p.S337G (on ENST00000487099 / NM_033334.4; = p.S332G on NM_001489.5) | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.216); catalogued as rs1044001672, COSV60637025; called by muse, mutect2, varscan2
- NVL | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs754254646, COSV55873564; called by muse, mutect2, varscan2
- OLAH | c.619T>A p.F207I (on ENST00000378228 / NM_001039702.3; = p.F260I on NM_018324.3) | Missense Mutation (SNP) | VAF 110/317 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65494082; called by muse, mutect2, varscan2
- OR2A7 | c.532del p.C178Vfs*37 | Frame Shift Del (DEL) | VAF 28/253 reads (11%) | catalogued as rs749245232; called by mutect2, pindel, varscan2
- OR4Q3 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 241/344 reads (70%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV59180032; called by muse, mutect2, varscan2
- OR4S2 | c.16A>G p.N6D | Missense Mutation (SNP) | VAF 73/103 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV56748068; called by muse, mutect2, varscan2
- OR51Q1 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 88/315 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs776951324, COSV56180319; called by muse, mutect2, varscan2
- OR5K4 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 334/911 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61584238; called by muse, mutect2, varscan2
- ORC1 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1026941164, COSV65365023; called by muse, mutect2, varscan2
- ORC3 | c.610del p.R204Gfs*16 | Frame Shift Del (DEL) | VAF 26/178 reads (15%) | catalogued as rs1336736903; called by mutect2, varscan2
- OTOGL | c.2293C>A p.L765I (on ENST00000547103; = p.L756I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV101509503; called by muse, mutect2, varscan2
- P4HA1 | c.76+1G>C p.X26_splice | Splice Site (SNP) | VAF 41/125 reads (33%) | catalogued as COSV54964787; called by muse, mutect2, varscan2
- PAAF1 | c.346A>G p.M116V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as COSV60157009; called by muse, mutect2, varscan2
- PAN3 | c.992T>C p.L331S | Missense Mutation (SNP) | VAF 160/456 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV66710757; called by muse, mutect2, varscan2
- PAQR7 | c.764_766del p.F255del | In Frame Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs752557686; called by pindel, varscan2
- PCARE | c.2285G>A p.C762Y | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.313); catalogued as COSV59057486; called by muse, mutect2, varscan2
- PCDHA11 | c.1429T>C p.S477P | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV56539266; called by muse, mutect2, varscan2
- PCDHA2 | c.2381T>C p.V794A | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); catalogued as rs1554120415, COSV65370592; called by muse, mutect2, varscan2
- PCDHGA3 | c.1401A>T p.R467S | Missense Mutation (SNP) | VAF 99/280 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.669); catalogued as COSV54016667; called by muse, mutect2, varscan2
- PCYT1A | c.495del p.F165Lfs*2 | Frame Shift Del (DEL) | VAF 54/259 reads (21%) | catalogued as rs750339641; called by mutect2, pindel, varscan2
- PDIA2 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371087103, COSV51992420; called by muse, mutect2, varscan2
- PDLIM1 | c.751A>T p.I251F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV61474824; called by muse, mutect2, varscan2
- PDXDC1 | c.1572-1G>T p.X524_splice | Splice Site (SNP) | VAF 143/365 reads (39%) | catalogued as COSV55075709; called by muse, mutect2, varscan2
- PEX7 | c.727T>C p.Y243H | Missense Mutation (SNP) | VAF 182/459 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.218); catalogued as COSV59251514; called by muse, mutect2, varscan2
- PGS1 | c.328A>G p.M110V | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as rs761343445, COSV53148135; called by muse, mutect2, varscan2
- PHB | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV55931701; called by muse, mutect2, varscan2
- PHLDB2 | c.3168+2T>G p.X1056_splice (on ENST00000393925 / NM_001134439.2; = p.X1013_splice on NM_145753.2) | Splice Site (SNP) | VAF 83/122 reads (68%) | catalogued as COSV67315362; called by muse, mutect2, varscan2
- PHTF1 | c.1916T>C p.L639P | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs191119223; called by muse, mutect2, varscan2
- PHYHIP | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV58689293; called by muse, mutect2, varscan2
- PI4KB | c.1567C>T p.R523* (on ENST00000368873 / NM_001369623.1; = p.R535* on NM_002651.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 40/335 reads (12%) | catalogued as COSV55020846; called by muse, mutect2, varscan2
- PIGO | c.2945C>T p.A982V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV53054606; called by muse, mutect2
- PIK3C3 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs749775725, COSV56283668; called by muse, mutect2, varscan2
- PIK3CD | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63127589, COSV63129715; called by muse, mutect2, varscan2
- PKN3 | c.2331del p.Y778Tfs*82 | Frame Shift Del (DEL) | VAF 18/106 reads (17%) | catalogued as COSV99403986; called by mutect2, pindel, varscan2
- PLA2G4D | c.1387T>A p.L463M | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV51823171; called by muse, mutect2, varscan2
- PLAT | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 115/332 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV54277624; called by muse, mutect2, varscan2
- PLCB3 | c.978C>A p.Y326* | Nonsense Mutation (SNP) | VAF 36/109 reads (33%) | catalogued as COSV54191763; called by muse, mutect2, varscan2
- PLCD1 | c.1711G>T p.G571C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52187594; called by muse, mutect2, varscan2
- PLEC | c.12385C>T p.R4129C (on ENST00000322810 / NM_201380.4; = p.R4019C on NM_000445.5) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs782528455, COSV59686569; called by muse, mutect2, varscan2
- PLEKHH2 | c.3605C>T p.P1202L | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV56759947; called by muse, mutect2, varscan2
- PML | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV51453008; called by muse, mutect2, varscan2
- POLM | c.1283C>A p.P428H | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV54243739; called by muse, mutect2, varscan2
- PRB4 | c.623del p.P208Qfs*49 | Frame Shift Del (DEL) | VAF 44/517 reads (9%) | catalogued as COSV54397651; called by mutect2, pindel
- PRB4 | c.437del p.P146Hfs*111 | Frame Shift Del (DEL) | VAF 194/1276 reads (15%) | catalogued as rs1414902343; called by mutect2, varscan2
- PRDM7 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.276); catalogued as COSV68322465, COSV68322654; called by muse, mutect2, varscan2
- PRKD3 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV52217686; called by muse, mutect2
- PRPF40B | c.1571G>T p.S524I (on ENST00000380281; = p.S518I on NM_012272.3) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56061444; called by muse, mutect2, varscan2
- PRPF8 | c.5999C>T p.A2000V | Missense Mutation (SNP) | VAF 100/342 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV56774075; called by muse, mutect2, varscan2
- PRPS1L1 | c.608A>G p.D203G | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.446); catalogued as COSV72649994; called by muse, mutect2, varscan2
- PRSS33 | c.835A>G p.S279G | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as COSV53451347; called by muse, mutect2
- PSMD1 | c.1580A>G p.Q527R | Missense Mutation (SNP) | VAF 68/230 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV58082783; called by muse, mutect2, varscan2
- PSMD11 | c.778A>G p.M260V | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs763761104, COSV55580819; called by muse, mutect2, varscan2
- PTGFRN | c.877A>G p.K293E | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV67799467; called by muse, mutect2, varscan2
- PTPRA | c.1288T>C p.C430R | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53787485; called by muse, mutect2, varscan2
- PTPRT | c.981T>A p.Y327* | Nonsense Mutation (SNP) | VAF 62/181 reads (34%) | catalogued as COSV62012327; called by muse, mutect2, varscan2
- QSER1 | c.550C>T p.R184* (on ENST00000399302; = p.R313* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 73/241 reads (30%) | catalogued as COSV67900027; called by muse, mutect2, varscan2
- QSER1 | c.3957A>C p.E1319D (on ENST00000399302; = p.E1448D on NM_001076786.3) | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV67901598; called by muse, mutect2, varscan2
- RAB1A | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV53127164; called by muse, mutect2, varscan2
- RABEP1 | c.2072T>C p.V691A | Missense Mutation (SNP) | VAF 129/389 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52587862; called by muse, mutect2
- RANBP2 | c.2250G>A p.M750I | Missense Mutation (SNP) | VAF 188/597 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV51707215; called by muse, mutect2, varscan2
- RAPH1 | c.3524G>A p.R1175Q | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs778650662, COSV55584462; called by muse, mutect2, varscan2
- RBM12B | c.2708T>C p.M903T | Missense Mutation (SNP) | VAF 181/479 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV67898754; called by muse, mutect2, varscan2
- RBM19 | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55697405; called by muse, mutect2
- RBM42 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1486964996, COSV52898055; called by muse, mutect2, varscan2
- REV3L | c.6130G>T p.D2044Y | Missense Mutation (SNP) | VAF 113/339 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV62622510; called by muse, mutect2, varscan2
- REV3L | c.1389G>A p.M463I | Missense Mutation (SNP) | VAF 126/445 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.095); catalogued as rs1264706290, COSV62622516; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs753959887; called by mutect2, varscan2
- RHCG | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745562643, COSV51517335; called by muse, mutect2, varscan2
- RHOU | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV64209025; called by muse, mutect2, varscan2
- RIPK2 | c.700A>G p.N234D | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV55134833; called by muse, mutect2, varscan2
- RNF14 | c.322A>G p.K108E | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.223); catalogued as rs750074718, COSV61662819; called by muse, mutect2, varscan2
- RNF43 | c.52A>G p.M18V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV60419084; called by muse, mutect2, varscan2
- ROBO2 | c.695T>A p.I232N | Missense Mutation (SNP) | VAF 73/136 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV59934144; called by muse, mutect2, varscan2
- RORC | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 123/348 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59092647, COSV59094637; called by muse, mutect2, varscan2
- RPTOR | c.512A>C p.Y171S | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60816638; called by muse, mutect2, varscan2
- RREB1 | c.1982A>G p.H661R | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58563989; called by muse, mutect2, varscan2
- RRP1B | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs750553115, COSV61480292; called by muse, mutect2, varscan2
- RTP5 | c.674dup p.A226Cfs*12 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | catalogued as rs35989328; called by mutect2, varscan2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs757259031; called by mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 70/159 reads (44%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SELENOP | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.034); catalogued as COSV100736910; called by muse, mutect2, varscan2
- SELPLG | c.769G>C p.A257P | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV57314545; called by muse, mutect2, varscan2
- SERAC1 | c.1895del p.K632Rfs*17 | Frame Shift Del (DEL) | VAF 39/128 reads (30%) | catalogued as COSV100894860; called by mutect2, pindel, varscan2
- SERPIND1 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs1172447883, COSV53140606; called by muse, mutect2, varscan2
- SERPINI1 | c.413A>G p.H138R | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55514286; called by muse, mutect2, varscan2
- SETD2 | c.4621A>C p.N1541H | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs755382206, COSV57448621; called by muse, mutect2, varscan2
- SHLD2 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV53958141; called by muse, mutect2, varscan2
- SIL1 | c.142A>G p.T48A | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.059); catalogued as rs185697854, COSV54528114; called by muse, mutect2, varscan2
- SIPA1L2 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV53398225; called by muse, mutect2, varscan2
- SLC11A1 | c.597del p.F199Lfs*5 | Frame Shift Del (DEL) | VAF 260/777 reads (33%) | catalogued as rs1362974823; called by mutect2, varscan2
- SLC26A7 | c.1597T>C p.C533R | Missense Mutation (SNP) | VAF 107/321 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as rs370346859; called by muse, mutect2, varscan2
- SLC38A11 | c.782T>C p.F261S (on ENST00000409149 / NM_001351539.1; = p.F239S on NM_173512.2) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58055778; called by muse, mutect2
- SLC3A2 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV63229713; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 52/167 reads (31%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC5A10 | c.1027G>A p.G343R (on ENST00000395645 / NM_001042450.4; = p.G359R on NM_152351.5) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771902838, COSV58761483; called by muse, mutect2, varscan2
- SLC5A11 | c.1493A>T p.D498V | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61743383; called by muse, mutect2, varscan2
- SLC6A12 | c.694del p.V232Sfs*17 | Frame Shift Del (DEL) | VAF 80/282 reads (28%) | catalogued as rs1287228150; called by mutect2, pindel, varscan2
- SLF2 | c.377A>G p.H126R | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV53278883; called by muse, mutect2, varscan2
- SLITRK6 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 113/306 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs375069918, COSV68389890; called by muse, mutect2, varscan2
- SMARCA4 | c.3547-2A>G p.X1183_splice | Splice Site (SNP) | VAF 28/57 reads (49%) | catalogued as COSV60806737; called by muse, mutect2, varscan2
- SMARCC1 | c.2490A>G p.S830= | Splice Region (SNP) | VAF 42/176 reads (24%) | catalogued as COSV54385605; called by muse, mutect2, varscan2
- SMCR8 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs969526584, COSV58174657; called by muse, mutect2, varscan2
- SMOX | c.965T>C p.L322P | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs199631589, COSV53864156; called by muse, mutect2, varscan2
- SNAPC5 | c.5T>C p.L2P | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs748097611, COSV57208182; called by muse, mutect2, varscan2
- SOAT1 | c.1157A>G p.H386R | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222153452, COSV62656556; called by muse, mutect2, varscan2
- SOCS3 | c.299del p.G100Afs*79 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs1480367425; called by mutect2, pindel, varscan2
- SOS2 | c.422T>C p.I141T | Missense Mutation (SNP) | VAF 208/304 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1378958999, COSV53573159; called by mutect2, varscan2
- SPEN | c.8858T>C p.I2953T | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs776343165, COSV65366737; called by muse, mutect2, varscan2
- SPNS2 | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61231470; called by muse, mutect2, varscan2
- SPRR3 | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs779381316, COSV54881079; called by muse, mutect2, varscan2
- SPTBN4 | c.5560C>T p.R1854W | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58953050; called by muse, mutect2, varscan2
- SRRT | c.863_865del p.E288del | In Frame Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs749020577; called by pindel, varscan2
- SSH3 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV57386453; called by muse, mutect2, varscan2
- ST18 | c.2840T>C p.M947T | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52506703; called by muse, mutect2, varscan2
- STAB1 | c.1496C>A p.S499Y | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV100402247; called by muse, mutect2, varscan2
- STAT6 | c.1063T>C p.C355R | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV55673738; called by muse, mutect2, varscan2
- STK38L | c.187-2A>G p.X63_splice | Splice Site (SNP) | VAF 51/137 reads (37%) | catalogued as COSV66522897; called by muse, mutect2, varscan2
- STKLD1 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64314614; called by muse, mutect2, varscan2
- STOML1 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV57552335; called by muse, mutect2, varscan2
- STRADA | c.997del p.R333Gfs*42 (on ENST00000336174 / NM_001363786.1; = p.R296Gfs*58 on NM_153335.6) | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs762120842, COSV51992441; called by mutect2, pindel, varscan2
- STRN | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV55751515; called by muse, mutect2
- STRN3 | c.528A>T p.R176S | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62581504; called by muse, mutect2, varscan2
- STX11 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.764); catalogued as rs372938807; called by muse, mutect2, varscan2
- SUCLG2 | c.958A>G p.I320V | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV56211366; called by muse, mutect2, varscan2
- SYNE1 | c.21688C>T p.Q7230* (on ENST00000367255 / NM_182961.4; = p.Q7159* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 50/154 reads (32%) | catalogued as COSV55079701; called by muse, varscan2
- SYNGR3 | c.659G>A p.S220N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV50192121, COSV50192557; called by muse, mutect2, varscan2
- TACC2 | c.2456C>T p.S819F | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV57770008; called by muse, mutect2, varscan2
- TBL3 | c.1130-2A>G p.X377_splice | Splice Site (SNP) | VAF 10/265 reads (4%) | catalogued as COSV60342873; called by muse, mutect2
- TDRD6 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.104); catalogued as COSV60175338, COSV60178145; called by muse, mutect2, varscan2
- TENM2 | c.5339A>G p.Y1780C (on ENST00000518659 / NM_001122679.2; = p.Y1541C on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV69139320; called by muse, mutect2, varscan2
- THOC6 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV50188161; called by muse, mutect2, varscan2
- THTPA | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55339583; called by muse, mutect2, varscan2
- TIAM1 | c.4646G>A p.R1549H | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.511); catalogued as rs143032407; called by muse, mutect2, varscan2
- TIAM1 | c.3774G>A p.E1258= | Splice Region (SNP) | VAF 31/107 reads (29%) | catalogued as COSV54546704; called by muse, mutect2, varscan2
- TINAGL1 | c.924del p.C309Vfs*2 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | catalogued as COSV54698324; called by mutect2, pindel
- TLN1 | c.3035A>C p.Q1012P | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV59211095; called by muse, mutect2, varscan2
- TLR10 | c.1394T>C p.L465P | Missense Mutation (SNP) | VAF 99/187 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58302005; called by muse, mutect2, varscan2
- TM2D2 | c.634A>G p.T212A (on ENST00000456397 / NM_078473.3; = p.T169A on NM_031940.4) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as COSV56760832; called by muse, mutect2, varscan2
- TMEM132D | c.2162C>T p.T721M | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs756460483, COSV67159566, COSV67161461; called by muse, mutect2, varscan2
- TMOD4 | c.128T>C p.M43T | Missense Mutation (SNP) | VAF 130/346 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54861817; called by muse, mutect2, varscan2
- TMTC1 | c.439A>G p.T147A (on ENST00000539277 / NM_001193451.2; = p.T39A on NM_175861.3) | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as COSV55491901; called by muse, mutect2, varscan2
- TMTC2 | c.2208del p.A737Qfs*4 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | catalogued as rs750447474; called by mutect2, pindel, varscan2
- TNC | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 28/55 reads (51%) | catalogued as COSV60789607; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV59529360; called by muse, mutect2, varscan2
- TNXB | c.11033G>A p.R3678Q (on ENST00000647633; = p.R3431Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1367983105, COSV64487665; called by muse, mutect2, varscan2
- TP53I3 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 33/95 reads (35%) | catalogued as COSV53188636; called by muse, mutect2, varscan2
- TREML4 | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV58386188; called by muse, mutect2, varscan2
- TRIM48 | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as COSV70162857; called by muse, mutect2, varscan2
- TRIM49 | c.411+1del p.X137_splice | Splice Site (DEL) | VAF 20/64 reads (31%) | catalogued as rs753749021; called by mutect2, varscan2
- TRIOBP | c.6953C>T p.S2318L (on ENST00000644935 / NM_001039141.3; = p.S605L on NM_007032.5) | Missense Mutation (SNP) | VAF 69/104 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1027682283, COSV60383446; called by muse, mutect2, varscan2
- TRPM2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201506177; called by muse, mutect2, varscan2
- TSHR | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 89/113 reads (79%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.946); catalogued as rs750198847, CM127299, COSV53329897; called by muse, mutect2, varscan2
- TSPOAP1 | c.3523G>T p.G1175C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV99272713; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 26/131 reads (20%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTN | c.12286G>T p.G4096C (on ENST00000591111; = p.G4050C on NM_003319.4) | Missense Mutation (SNP) | VAF 57/184 reads (31%) | catalogued as COSV60293944; called by muse, mutect2, varscan2
- TUFT1 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.691); catalogued as rs113585307, COSV61950248; called by muse, mutect2, varscan2
- UCN3 | c.311G>T p.R104M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV66824272; called by muse, mutect2, varscan2
- UGT1A1 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as rs762109713, COSV59392563, COSV59396677; called by muse, mutect2
- UHRF1BP1L | c.190A>G p.N64D | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54441789; called by muse, mutect2, varscan2
- UMODL1 | c.1082A>G p.Q361R | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61161323; called by muse, mutect2
- UNC79 | c.4573C>T p.R1525W (on ENST00000393151 / NM_001346218.2; = p.R1348W on NM_020818.5) | Missense Mutation (SNP) | VAF 125/187 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs1052514724, COSV56404196; called by muse, mutect2, varscan2
- UNG | c.758T>G p.L253R (on ENST00000242576 / NM_080911.3; = p.L244R on NM_003362.4) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99655456; called by muse, mutect2, varscan2
- UPRT | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV64920505; called by muse, mutect2, varscan2
- UQCC1 | c.404T>A p.L135Q | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV62903399; called by muse, varscan2
- USP43 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV53306285; called by muse, mutect2, varscan2
- USP43 | c.2882T>C p.M961T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV53306014; called by muse, mutect2, varscan2
- USP50 | c.671A>G p.Y224C (on ENST00000616326; = p.Y215C on NM_203494.5) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs1178112491, COSV73214290; called by muse, mutect2, varscan2
- VPS18 | c.1343T>C p.L448P | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.222); catalogued as COSV55031938; called by muse, mutect2, varscan2
- VWF | c.7886T>C p.L2629P | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV54632116; called by muse, mutect2, varscan2
- VWF | c.5596T>C p.S1866P | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV54632129; called by muse, mutect2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 66/222 reads (30%) | catalogued as rs773064295, COSV51967888; called by mutect2, varscan2
- WDR72 | c.2551A>G p.S851G | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV64752788; called by muse, mutect2
- WTAP | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV61610523; called by muse, mutect2, varscan2
- WWP2 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1036291469, COSV63127192; called by muse, mutect2, varscan2
- XIRP2 | c.1547C>A p.T516N (on ENST00000628543; = p.T691N on NM_152381.6) | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV54729246; called by muse, mutect2, varscan2
- ZBED4 | c.3329C>A p.S1110Y | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.69); catalogued as COSV53467826; called by muse, mutect2, varscan2
- ZBTB4 | c.2596A>G p.S866G | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60142080; called by muse, mutect2, varscan2
- ZDHHC7 | c.831del p.S280Hfs*5 | Frame Shift Del (DEL) | VAF 34/110 reads (31%) | catalogued as COSV58214455; called by mutect2, pindel, varscan2
- ZFHX3 | c.3856A>G p.I1286V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as rs765001204, COSV51732558; called by muse, mutect2, varscan2
- ZFHX4 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV51491259; called by muse, mutect2, varscan2
- ZFP42 | c.531del p.I178* | Frame Shift Del (DEL) | VAF 23/230 reads (10%) | catalogued as rs1403527187; called by mutect2, pindel, varscan2
- ZIK1 | c.34-1G>A p.X12_splice | Splice Site (SNP) | VAF 47/139 reads (34%) | catalogued as COSV56738285; called by muse, mutect2, varscan2
- ZMYM3 | c.2960A>G p.N987S | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.428); catalogued as COSV58740326; called by muse, mutect2, varscan2
- ZNF12 | c.1222C>G p.L408V (on ENST00000405858 / NM_016265.4; = p.L370V on NM_006956.3) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV61245427; called by muse, mutect2, varscan2
- ZNF217 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56601421; called by muse, mutect2, varscan2
- ZNF221 | c.1514C>A p.P505H | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52108589, COSV52110943; called by muse, mutect2, varscan2
- ZNF234 | c.836A>G p.Q279R | Missense Mutation (SNP) | VAF 112/347 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV70604042; called by muse, mutect2, varscan2
- ZNF319 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1252247690, COSV54623630; called by muse, mutect2, varscan2
- ZNF354A | c.1516A>T p.N506Y | Missense Mutation (SNP) | VAF 92/276 reads (33%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.996); catalogued as COSV59984647; called by muse, mutect2, varscan2
- ZNF408 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1337910600, COSV61239141; called by muse, mutect2, varscan2
- ZNF433 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 75/228 reads (33%) | catalogued as COSV61400140; called by muse, mutect2, varscan2
- ZNF462 | c.6463C>T p.Q2155* | Nonsense Mutation (SNP) | VAF 6/95 reads (6%) | catalogued as COSV52949375; called by muse, mutect2
- ZNF544 | c.866A>G p.K289R | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV54138195; called by muse, mutect2, varscan2
- ZNF57 | c.1651A>G p.S551G | Missense Mutation (SNP) | VAF 68/123 reads (55%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); catalogued as COSV60983219; called by muse, mutect2, varscan2
- ZNF638 | c.5528T>C p.I1843T | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1328658402, COSV52495300; called by muse, mutect2, varscan2
- ZNF687 | c.1051T>C p.S351P | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV55020836; called by muse, mutect2, varscan2
- ZNF750 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs778933111, COSV53962453; called by muse, mutect2, varscan2
- ZNF862 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as COSV56225775; called by muse, mutect2
- ZSCAN29 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs1354921709, COSV67823212; called by muse, mutect2, varscan2
- AC008397.2 | c.1062del p.Q355Rfs*6 | Frame Shift Del (DEL) | VAF 45/143 reads (31%) | called by mutect2, pindel, varscan2
- ACBD4 | c.477dup p.K160Qfs*23 | Frame Shift Ins (INS) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- ACSM3 | c.1089del p.K363Nfs*21 | Frame Shift Del (DEL) | VAF 55/200 reads (28%) | called by mutect2, pindel, varscan2
- ADNP2 | c.2219del p.K740Sfs*3 | Frame Shift Del (DEL) | VAF 65/214 reads (30%) | called by mutect2, pindel, varscan2
- AHCTF1 | c.6596del p.N2199Tfs*12 (on ENST00000366508; = p.N2173Tfs*12 on NM_015446.5) | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | called by mutect2, pindel, varscan2
- AKAP11 | c.1584del p.F528Lfs*17 | Frame Shift Del (DEL) | VAF 40/126 reads (32%) | called by mutect2, varscan2
- AKIP1 | c.385del p.C129Afs*4 | Frame Shift Del (DEL) | VAF 34/128 reads (27%) | called by mutect2, pindel, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 46/136 reads (34%) | called by mutect2, varscan2
- APC | c.5058dup p.R1687Tfs*13 | Frame Shift Ins (INS) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- ARHGAP30 | c.210del p.F70Lfs*49 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- ATAD2B | c.2202_2205del p.H734Qfs*57 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | called by mutect2, pindel, varscan2
- BBX | c.2088dup p.F697Ifs*8 | Frame Shift Ins (INS) | VAF 60/194 reads (31%) | called by mutect2, varscan2
- BRCC3 | c.646dup p.I216Nfs*15 | Frame Shift Ins (INS) | VAF 32/68 reads (47%) | called by mutect2, pindel, varscan2
- CDH10 | c.1920dup p.E641Rfs*18 | Frame Shift Ins (INS) | VAF 49/164 reads (30%) | called by mutect2, varscan2
- CDKAL1 | c.1722del p.F574Lfs*39 | Frame Shift Del (DEL) | VAF 22/186 reads (12%) | called by mutect2, pindel, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | called by mutect2, pindel, varscan2
- CLDN4 | c.537del p.L180Cfs*115 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- CLDN6 | c.567del p.S190Pfs*70 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel
- COPA | c.512dup p.N171Kfs*18 | Frame Shift Ins (INS) | VAF 68/250 reads (27%) | called by mutect2, varscan2
- CPNE1 | c.715-2_715delinsC p.X239_splice (on ENST00000352393; = p.X244_splice on NM_003915.5) | Splice Site (DEL) | VAF 28/147 reads (19%) | called by pindel, varscan2*
- CR2 | c.826dup p.C276Lfs*31 | Frame Shift Ins (INS) | VAF 74/227 reads (33%) | called by mutect2, pindel, varscan2
- CSMD3 | c.5214_5215del p.L1739Hfs*7 (on ENST00000297405 / NM_001363185.1; = p.L1635Hfs*7 on NM_052900.3) | Frame Shift Del (DEL) | VAF 66/272 reads (24%) | called by pindel, varscan2
- CYFIP1 | c.1527T>C p.S509= | Splice Region (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2, varscan2
- DNAJC17 | c.598_600del p.K200del | In Frame Del (DEL) | VAF 24/93 reads (26%) | called by mutect2, pindel, varscan2
- EIF3L | c.440del p.X147_splice | Splice Site (DEL) | VAF 65/133 reads (49%) | called by mutect2, pindel, varscan2
- EMC2 | c.410del p.N137Mfs*8 | Frame Shift Del (DEL) | VAF 9/97 reads (9%) | called by mutect2, pindel
- EPB41 | c.121del p.T41Qfs*13 | Frame Shift Del (DEL) | VAF 92/193 reads (48%) | called by mutect2, pindel, varscan2
- EXOC6B | c.1269del p.F423Lfs*5 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- FAAH | c.647del p.G216Afs*19 | Frame Shift Del (DEL) | VAF 54/172 reads (31%) | called by mutect2, pindel, varscan2
- FAM120A | c.1157del p.G386Afs*27 | Frame Shift Del (DEL) | VAF 7/12 reads (58%) | called by mutect2, varscan2
- FBXO11 | c.1455del p.A486Pfs*31 (on ENST00000403359 / NM_001190274.2; = p.A402Pfs*31 on NM_025133.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | called by mutect2, pindel, varscan2
- FNIP1 | c.245_246del p.K82Sfs*20 | Frame Shift Del (DEL) | VAF 56/187 reads (30%) | called by mutect2, pindel, varscan2
- GABRQ | c.1751del p.P584Qfs*109 | Frame Shift Del (DEL) | VAF 45/131 reads (34%) | called by mutect2, pindel, varscan2
- GCN1 | c.4053del p.S1352Pfs*8 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | called by mutect2, pindel, varscan2
- GINM1 | c.585del p.E196Kfs*21 | Frame Shift Del (DEL) | VAF 35/324 reads (11%) | called by mutect2, pindel
- GUCY2C | c.2177del p.N726Tfs*39 | Frame Shift Del (DEL) | VAF 48/214 reads (22%) | called by pindel, varscan2
- HNRNPUL2 | c.1792_1793del p.L598Afs*2 | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- IFIT3 | c.293del p.G98Efs*20 | Frame Shift Del (DEL) | VAF 40/154 reads (26%) | called by mutect2, varscan2
- IFT88 | c.1358del p.K453Rfs*5 (on ENST00000319980 / NM_001318493.2; = p.K444Rfs*5 on NM_006531.5 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 81/249 reads (33%) | called by mutect2, pindel, varscan2
- IGFBP7 | c.828del p.G277Vfs*13 | Frame Shift Del (DEL) | VAF 46/114 reads (40%) | called by pindel, varscan2
- KDM6B | c.107del p.P36Lfs*162 | Frame Shift Del (DEL) | VAF 45/173 reads (26%) | called by mutect2, pindel, varscan2
- KLHL31 | c.557del p.N186Mfs*24 | Frame Shift Del (DEL) | VAF 64/203 reads (32%) | called by mutect2, pindel, varscan2
- LAMP1 | c.456del p.K152Nfs*12 | Frame Shift Del (DEL) | VAF 62/198 reads (31%) | called by mutect2, pindel, varscan2
- LONRF1 | c.1461_1466del p.F487_P489delinsL | In Frame Del (DEL) | VAF 15/37 reads (41%) | called by mutect2, pindel, varscan2
- LRRFIP2 | c.1134del p.K378Nfs*12 | Frame Shift Del (DEL) | VAF 62/146 reads (42%) | called by mutect2, pindel, varscan2
- LRRN4 | c.937del p.L313Sfs*19 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- MBOAT1 | c.264dup p.V89Cfs*14 | Frame Shift Ins (INS) | VAF 84/286 reads (29%) | called by mutect2, pindel, varscan2
- MKI67 | c.2236del p.M746Wfs*10 | Frame Shift Del (DEL) | VAF 50/208 reads (24%) | called by mutect2, varscan2
- MLH1 | c.1497_1498insCTC p.R499_I500insL | In Frame Ins (INS) | VAF 140/294 reads (48%) | called by mutect2, varscan2*
- MLH1 | c.1499_1500insTAACCTCA p.I501Nfs*10 | Frame Shift Ins (INS) | VAF 147/305 reads (48%) | called by mutect2, varscan2*
- MUC16 | c.27745_27753del p.K9249_T9251del | In Frame Del (DEL) | VAF 37/85 reads (44%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.4517_4519del p.N1506del (on ENST00000357337; = p.N1544del on NM_015057.5) | In Frame Del (DEL) | VAF 45/163 reads (28%) | called by pindel, varscan2
- NBPF11 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 172/308 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- NOL10 | c.1596del p.E533Kfs*42 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- NOXA1 | c.844_845del p.S282Pfs*15 | Frame Shift Del (DEL) | VAF 17/37 reads (46%) | called by pindel, varscan2
- OR2T34 | c.25_27del p.Q9del | In Frame Del (DEL) | VAF 36/153 reads (24%) | called by mutect2, pindel, varscan2
- ORAI1 | c.507_508insAG p.R170Sfs*20 | Frame Shift Ins (INS) | VAF 13/41 reads (32%) | called by muse*, mutect2, varscan2*
- PHF3 | c.1650dup p.Q551Tfs*3 | Frame Shift Ins (INS) | VAF 37/90 reads (41%) | called by mutect2, varscan2
- PI4KB | c.474del p.Y159Tfs*40 (on ENST00000368873 / NM_001369623.1; = p.Y171Tfs*40 on NM_002651.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 52/166 reads (31%) | called by mutect2, pindel, varscan2
- PIGN | c.699del p.V234Lfs*32 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | called by mutect2, pindel, varscan2
- PLEKHG2 | c.2677del p.L893Wfs*153 | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- POTEM | c.1265A>G p.H422R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.301); called by mutect2, varscan2
- PPFIA3 | c.2032del p.R678Afs*50 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- PPP1R16B | c.1666_1667del p.M556Gfs*16 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- PPP4R3A | c.2203_2204del p.N735Pfs*20 (on ENST00000554943 / NM_001366432.1; = p.N722Pfs*20 on NM_001284280.1) | Frame Shift Del (DEL) | VAF 185/340 reads (54%) | called by mutect2, pindel, varscan2
- RALGAPA1 | c.2260del p.T754Lfs*33 | Frame Shift Del (DEL) | VAF 70/255 reads (27%) | called by mutect2, varscan2
- RASL10B | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- RPS6KB1 | c.977del p.K326Sfs*3 | Frame Shift Del (DEL) | VAF 26/91 reads (29%) | called by mutect2, pindel, varscan2
- SLC22A4 | c.943del p.S315Lfs*5 | Frame Shift Del (DEL) | VAF 32/137 reads (23%) | called by mutect2, pindel, varscan2
- SLC7A6 | c.563dup p.T189Hfs*25 | Frame Shift Ins (INS) | VAF 44/153 reads (29%) | called by mutect2, pindel, varscan2
- SMARCC2 | c.1754del p.K585Rfs*72 | Frame Shift Del (DEL) | VAF 56/172 reads (33%) | called by mutect2, varscan2
- SMARCD2 | c.1269del p.L424Wfs*27 | Frame Shift Del (DEL) | VAF 48/141 reads (34%) | called by mutect2, varscan2
- SRCIN1 | c.3130C>A p.R1044S (on ENST00000621492; = p.R1010S on NM_025248.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- THSD7A | c.488_491del p.K163Tfs*72 | Frame Shift Del (DEL) | VAF 30/102 reads (29%) | called by mutect2, pindel, varscan2
- TMCC2 | c.1345del p.L449Wfs*13 | Frame Shift Del (DEL) | VAF 31/122 reads (25%) | called by mutect2, pindel, varscan2
- TMF1 | c.1788del p.V597Lfs*4 | Frame Shift Del (DEL) | VAF 56/157 reads (36%) | called by mutect2, pindel, varscan2
- TRPM4 | c.470dup p.L158Sfs*40 | Frame Shift Ins (INS) | VAF 55/225 reads (24%) | called by mutect2, pindel, varscan2
- UBQLN4 | c.1585del p.A529Lfs*12 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- ZC3H7A | c.2349del p.K783Nfs*23 | Frame Shift Del (DEL) | VAF 60/170 reads (35%) | called by mutect2, varscan2
- ZFP82 | c.1587_1590del p.N529Kfs*13 | Frame Shift Del (DEL) | VAF 35/94 reads (37%) | called by mutect2, pindel, varscan2
- ZMYM5 | c.1982del p.N661Mfs*40 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- ZNF619 | c.171del p.R58Efs*15 | Frame Shift Del (DEL) | VAF 50/128 reads (39%) | called by mutect2, pindel, varscan2
- ABCG4 | c.558G>A p.T186= | Silent (SNP) | VAF 55/186 reads (30%) | catalogued as rs375767553; called by muse, mutect2, varscan2
- ACSL4 | c.1248T>C p.D416= (on ENST00000340800 / NM_022977.2; = p.D375= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 84/151 reads (56%) | catalogued as COSV61615633; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2970G>A p.T990= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as rs368789447, COSV55005111; called by muse, mutect2, varscan2
- ADD2 | c.1032C>T p.S344= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs369508265, COSV52455645; called by muse, mutect2, varscan2
- AGBL1 | c.984A>G p.E328= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV66870492; called by muse, mutect2
- AHDC1 | c.2913C>T p.Y971= | Silent (SNP) | VAF 60/111 reads (54%) | catalogued as rs776936156, COSV55940736; called by muse, mutect2, varscan2
- ALS2 | c.3027A>G p.R1009= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV51891870; called by muse, mutect2
- ANKH | c.1308C>T p.G436= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs376655130; called by muse, mutect2, varscan2
- ANXA5 | c.261C>A p.P87= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV56640032; called by muse, mutect2, varscan2
- APAF1 | c.2658T>C p.H886= (on ENST00000551964 / NM_181861.2; = p.H832= on NM_001160.3) | Silent (SNP) | VAF 97/279 reads (35%) | catalogued as COSV59667791; called by muse, mutect2, varscan2
- APBB1 | c.669C>T p.S223= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV54979992; called by muse, mutect2, varscan2
- APOB | c.6384A>G p.S2128= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as COSV51949474; called by muse, mutect2, varscan2
- APOBEC3D | c.660A>G p.L220= | Silent (SNP) | VAF 57/107 reads (53%) | catalogued as COSV53328398; called by muse, mutect2, varscan2
- ARFGEF2 | c.3156G>A p.Q1052= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as rs1368856239, COSV64214694; called by muse, mutect2, varscan2
- ARFGEF3 | c.1686C>T p.V562= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs767772151, COSV52468734; called by mutect2, varscan2
- ARRB1 | c.909C>T p.S303= | Silent (SNP) | VAF 20/308 reads (6%) | catalogued as COSV63577286; called by muse, mutect2
- ASXL2 | c.2334A>C p.P778= | Silent (SNP) | VAF 50/164 reads (30%) | catalogued as COSV55466459; called by muse, mutect2, varscan2
- ATP10A | c.1192T>C p.L398= | Silent (SNP) | VAF 61/212 reads (29%) | catalogued as COSV63522761; called by muse, mutect2, varscan2
- ATRNL1 | c.3057T>C p.H1019= | Silent (SNP) | VAF 47/128 reads (37%) | catalogued as COSV58110913; called by muse, mutect2, varscan2
- BRD9 | c.873G>A p.T291= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as rs540220873, COSV60249597; called by muse, mutect2, varscan2
- C1QTNF5 | c.723C>G p.V241= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV100264936; called by muse, mutect2, varscan2
- CATSPERG | c.2292T>C p.T764= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV53052896; called by muse, mutect2, varscan2
- CD4 | c.516T>A p.S172= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV50595138; called by muse, mutect2, varscan2
- CFAP36 | c.123T>C p.D41= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs775362373, COSV59119032; called by muse, mutect2, varscan2
- CLK4 | c.456A>G p.G152= | Silent (SNP) | VAF 37/136 reads (27%) | catalogued as COSV60320738; called by muse, mutect2, varscan2
- CORO1B | c.954T>C p.G318= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV57053902; called by muse, mutect2, varscan2
- CPA1 | c.750C>T p.G250= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as rs1188484065, COSV50574126; called by muse, mutect2, varscan2
- CRACD | c.2532G>A p.P844= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV51717282; called by muse, mutect2, varscan2
- CSMD1 | c.639C>T p.R213= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs777613399, COSV68233215; called by muse, mutect2
- CSRP2 | c.130T>C p.L44= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as COSV60703406; called by muse, mutect2, varscan2
- CXXC1 | c.153T>C p.H51= | Silent (SNP) | VAF 56/212 reads (26%) | catalogued as rs777899832, COSV53276537; called by muse, mutect2, varscan2
- DCUN1D3 | c.912T>C p.T304= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1416216630, COSV60954653; called by muse, mutect2, varscan2
- DENND4B | c.3957C>T p.G1319= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs1180900626, COSV63411486; called by muse, mutect2, varscan2
- DGKH | c.3342T>C p.P1114= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV54939709; called by muse, mutect2, varscan2
- DHX58 | c.339C>T p.S113= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs782795082, COSV52427927; called by muse, mutect2, varscan2
- DHX8 | c.1680G>A p.E560= | Silent (SNP) | VAF 77/231 reads (33%) | catalogued as COSV52256079; called by muse, mutect2, varscan2
- DISP2 | c.3030C>T p.L1010= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV51117013; called by muse, mutect2, varscan2
- DMBX1 | c.87G>A p.Q29= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV63602519; called by muse, mutect2, varscan2
- DMWD | c.675G>A p.S225= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs763247338, COSV52181754, COSV99353396; called by muse, mutect2, varscan2
- DOP1B | c.1150T>C p.L384= | Silent (SNP) | VAF 190/542 reads (35%) | catalogued as COSV67695655; called by muse, varscan2
- DSC3 | c.1197T>C p.N399= | Silent (SNP) | VAF 88/256 reads (34%) | catalogued as COSV64575022; called by muse, mutect2, varscan2
- DSP | c.5697C>A p.I1899= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as COSV101131550, COSV65795174; called by muse, mutect2, varscan2
- ECEL1 | c.1560T>C p.D520= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1289873823, COSV58814039; called by muse, mutect2, varscan2
- EGLN2 | c.516T>A p.S172= | Silent (SNP) | VAF 37/117 reads (32%) | catalogued as COSV100393846; called by muse, mutect2, varscan2
- EIF4A3 | c.423T>C p.I141= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as COSV53921920; called by muse, mutect2, varscan2
- ELANE | c.93G>T p.V31= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs894935356, COSV52256221; called by muse, mutect2, varscan2
- ENG | c.1701T>C p.T567= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV61228639; called by muse, mutect2, varscan2
- EP300 | c.6597A>G p.P2199= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV54343172; called by muse, mutect2, varscan2
- EPHB6 | c.393C>T p.Y131= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as COSV67420542; called by muse, mutect2, varscan2
- ERBB2 | c.2844C>A p.T948= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV54080748; called by muse, mutect2, varscan2
- ESR1 | c.1054A>C p.R352= | Silent (SNP) | VAF 15/198 reads (8%) | catalogued as COSV52800263; called by muse, mutect2
- EXD3 | c.1794C>T p.G598= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV59812648; called by muse, mutect2, varscan2
- F8 | c.3745C>T p.L1249= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as COSV64273702, COSV64277857; called by muse, mutect2, varscan2
- FAM131A | c.834C>A p.P278= (on ENST00000310585; = p.P309= on NM_144635.5) | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as COSV55603772; called by muse, mutect2, varscan2
- FAM184A | c.2211G>A p.E737= | Silent (SNP) | VAF 69/192 reads (36%) | catalogued as COSV58857894; called by muse, mutect2, varscan2
- FCGBP | c.7131C>T p.F2377= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as rs755766638; called by muse, varscan2
- FTO | c.1215A>G p.A405= | Silent (SNP) | VAF 56/175 reads (32%) | catalogued as COSV67113822; called by muse, mutect2, varscan2
- GASK1B | c.142T>C p.L48= | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as COSV56711266; called by muse, mutect2, varscan2
- GDF10 | c.514C>T p.L172= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs943469958; called by muse, mutect2
- GPR149 | c.588C>T p.I196= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs1358765958, COSV67669476; called by muse, mutect2, varscan2
- HDAC9 | c.1560G>A p.A520= | Silent (SNP) | VAF 39/117 reads (33%) | catalogued as COSV67783531; called by muse, mutect2, varscan2
- HTR5A | c.600C>T p.Y200= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs577000054, COSV55286528; called by muse, mutect2, varscan2
- IFIT1B | c.241T>C p.L81= | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as COSV65663698; called by muse, mutect2, varscan2
- IFNA7 | c.222T>A p.T74= | Silent (SNP) | VAF 96/188 reads (51%) | catalogued as COSV99497601; called by muse, mutect2, varscan2
- IGSF10 | c.6147A>G p.Q2049= | Silent (SNP) | VAF 116/332 reads (35%) | catalogued as COSV56393953; called by muse, mutect2, varscan2
- INPP4B | c.2427C>A p.L809= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV53741618; called by muse, mutect2, varscan2
- IPMK | c.987T>C p.H329= | Silent (SNP) | VAF 52/588 reads (9%) | catalogued as COSV64244468; called by muse, mutect2
- ITGA5 | c.1681C>T p.L561= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV53220243, COSV53221502; called by muse, mutect2, varscan2
- IYD | c.69C>A p.A23= | Silent (SNP) | VAF 172/472 reads (36%) | catalogued as COSV57599497, COSV57603530; called by muse, varscan2
- JADE3 | c.1233A>G p.V411= | Silent (SNP) | VAF 36/59 reads (61%) | catalogued as COSV54469587; called by muse, mutect2, varscan2
- KIF5A | c.3033G>A p.P1011= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs148434838; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT2 | c.537T>C p.R179= | Silent (SNP) | VAF 21/259 reads (8%) | catalogued as COSV59012414; called by muse, mutect2
- LAMA1 | c.8472G>T p.V2824= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV67543349; called by muse, mutect2, varscan2
- LEFTY2 | c.151C>T p.L51= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV64747603; called by muse, mutect2, varscan2
- LNPEP | c.2304C>A p.A768= | Silent (SNP) | VAF 73/195 reads (37%) | catalogued as COSV51477795, COSV51480730; called by muse, mutect2, varscan2
- LRIG3 | c.1524G>A p.Q508= | Silent (SNP) | VAF 119/374 reads (32%) | catalogued as COSV57869146; called by muse, mutect2, varscan2
- LRP1 | c.12984C>T p.C4328= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV54516549; called by muse, mutect2, varscan2
- LRP2 | c.10812A>G p.K3604= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV55570248; called by muse, mutect2, varscan2
- LRRC43 | c.771A>T p.G257= | Silent (SNP) | VAF 49/146 reads (34%) | catalogued as COSV60292898; called by muse, mutect2, varscan2
- MARCHF8 | c.723T>C p.C241= | Silent (SNP) | VAF 89/337 reads (26%) | catalogued as COSV60574480; called by muse, mutect2, varscan2
- MARS1 | c.1284C>T p.V428= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs752350446, COSV100007747, COSV56258169; called by muse, mutect2
- MYOM2 | c.468C>A p.I156= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs1272873948, COSV50760824; called by muse, mutect2, varscan2
- NBPF10 | c.11136A>G p.P3712= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as rs782794784, COSV61671248; called by muse, mutect2, varscan2
- NEB | c.3612C>G p.G1204= | Silent (SNP) | VAF 189/571 reads (33%) | catalogued as COSV51453694; called by muse, mutect2, varscan2
- NES | c.1416T>C p.P472= | Silent (SNP) | VAF 83/236 reads (35%) | catalogued as COSV63962628; called by muse, mutect2, varscan2
- NFS1 | c.1113G>A p.K371= | Silent (SNP) | VAF 72/219 reads (33%) | catalogued as COSV65054250; called by muse, varscan2
- NOVA2 | c.867C>T p.Y289= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs766556271, COSV99611112; called by muse, mutect2
- NPAS4 | c.1803T>C p.D601= | Silent (SNP) | VAF 84/205 reads (41%) | catalogued as COSV60652498; called by muse, mutect2, varscan2
- PAG1 | c.315C>T p.Y105= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs113484085; called by muse, mutect2, varscan2
- PASD1 | c.168T>C p.C56= | Silent (SNP) | VAF 37/267 reads (14%) | catalogued as COSV64857308; called by muse, mutect2, varscan2
- PEMT | c.147C>A p.P49= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV55133149; called by muse, mutect2, varscan2
- PEX11B | c.408C>T p.S136= | Silent (SNP) | VAF 109/196 reads (56%) | catalogued as COSV65198892; called by muse, mutect2, varscan2
- PHLPP1 | c.3186T>C p.L1062= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV53036713; called by muse, mutect2
- PIP4K2B | c.912C>T p.D304= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs756733791; called by muse, mutect2, varscan2
- PPP1R9A | c.279T>C p.H93= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as COSV56907964; called by muse, mutect2, varscan2
- PYGO1 | c.105A>G p.P35= | Silent (SNP) | VAF 53/154 reads (34%) | catalogued as COSV57349865; called by muse, mutect2, varscan2
- RAD52 | c.354T>C p.G118= | Silent (SNP) | VAF 52/375 reads (14%) | catalogued as rs768303684, COSV57274197; called by muse, mutect2, varscan2
- RB1 | c.2709A>G p.E903= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV57323577; called by muse, mutect2, varscan2
- RHOXF1 | c.72A>G p.T24= | Silent (SNP) | VAF 40/73 reads (55%) | catalogued as COSV54295626; called by muse, mutect2, varscan2
- RNF19A | c.492G>A p.R164= | Silent (SNP) | VAF 84/294 reads (29%) | catalogued as COSV61994540; called by muse, mutect2, varscan2
- RNF217 | c.1302A>G p.E434= (on ENST00000521654 / NM_001286398.2; = p.E142= on NM_152553.5) | Silent (SNP) | VAF 48/162 reads (30%) | catalogued as rs1273424725, COSV51577302; called by muse, mutect2, varscan2
- RNF31 | c.1105C>T p.L369= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV53761027; called by muse, mutect2, varscan2
- RORC | c.129C>T p.Y43= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs200606878, COSV59095189; called by muse, mutect2, varscan2
- SAMD15 | c.952A>C p.R318= | Silent (SNP) | VAF 37/126 reads (29%) | catalogued as COSV53627789; called by muse, mutect2, varscan2
- SEC13 | c.597C>T p.D199= (on ENST00000350697 / NM_183352.3; = p.D202= on NM_030673.4) | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as rs752161884, COSV61601266; called by muse, mutect2, varscan2
- SERTAD2 | c.369T>C p.T123= | Silent (SNP) | VAF 47/105 reads (45%) | catalogued as COSV57641106; called by muse, mutect2, varscan2
- SH3GL2 | c.336A>G p.P112= | Silent (SNP) | VAF 64/135 reads (47%) | catalogued as rs1457959044, COSV66054453; called by muse, mutect2, varscan2
- SIGLEC11 | c.1593C>T p.R531= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV70222123; called by muse, mutect2, varscan2
- SNAP91 | c.1731G>T p.A577= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99536622; called by muse, varscan2
- SNRNP200 | c.5826T>C p.A1942= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as COSV55531491; called by muse, mutect2, varscan2
- SPG11 | c.4344C>T p.C1448= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as COSV56001035; called by muse, mutect2, varscan2
- SYVN1 | c.762G>A p.Q254= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV53697044; called by muse, mutect2, varscan2
- TAAR5 | c.699T>C p.I233= | Silent (SNP) | VAF 49/118 reads (42%) | catalogued as COSV57799748; called by muse, mutect2, varscan2
- TAGLN3 | c.324C>A p.T108= | Silent (SNP) | VAF 121/354 reads (34%) | catalogued as rs369661291, COSV56329071; called by muse, mutect2, varscan2
- TBC1D17 | c.1611G>A p.E537= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV55580982; called by muse, mutect2, varscan2
- TBC1D23 | c.2049T>A p.T683= (on ENST00000394144 / NM_001199198.3; = p.T668= on NM_018309.5) | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100792611, COSV61370029; called by muse, mutect2, varscan2
- TEK | c.1134T>C p.P378= | Silent (SNP) | VAF 135/263 reads (51%) | catalogued as COSV66232769; called by muse, mutect2, varscan2
- TMCC1 | c.261C>T p.N87= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as rs751562317, COSV67874516; called by muse, mutect2, varscan2
- TMCC3 | c.957T>C p.Y319= | Silent (SNP) | VAF 23/159 reads (14%) | catalogued as COSV54157182; called by muse, mutect2, varscan2
- TMEM38B | c.792C>A p.S264= | Silent (SNP) | VAF 71/127 reads (56%) | catalogued as COSV65950655; called by muse, mutect2, varscan2
- TMEM97 | c.426C>T p.T142= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV56879455; called by muse, mutect2, varscan2
- TNXB | c.10143C>T p.G3381= (on ENST00000647633; = p.G3134= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV64487669; called by muse, mutect2, varscan2
- TRAPPC1 | c.339C>T p.P113= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as rs1422245736, COSV58050996; called by muse, mutect2, varscan2
- TRMT1 | c.1053C>T p.C351= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as rs139341662; called by muse, mutect2, varscan2
- TUBB | c.642T>A p.T214= | Silent (SNP) | VAF 43/146 reads (29%) | catalogued as COSV58358262; called by muse, mutect2, varscan2
- UBAP2L | c.2034C>T p.G678= | Silent (SNP) | VAF 45/262 reads (17%) | catalogued as COSV55179904; called by muse, mutect2, varscan2
- UBQLN3 | c.1272T>C p.G424= | Silent (SNP) | VAF 77/209 reads (37%) | catalogued as rs773124058, COSV61165414; called by muse, mutect2, varscan2
- USP19 | c.1350T>C p.H450= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as rs750878548, COSV60048173; called by muse, mutect2, varscan2
- VARS1 | c.831C>T p.V277= | Silent (SNP) | VAF 61/168 reads (36%) | catalogued as COSV65155633; called by muse, mutect2, varscan2
- VSTM2L | c.405G>A p.T135= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs773296427, COSV65095438, COSV65096496; called by muse, mutect2, varscan2
- WDHD1 | c.3177T>C p.T1059= | Silent (SNP) | VAF 90/246 reads (37%) | catalogued as COSV62215365; called by muse, mutect2, varscan2
- WNK2 | c.4677C>T p.T1559= (on ENST00000297954 / NM_001282394.1; = p.T1522= on NM_006648.3) | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs368320959; called by muse, mutect2, varscan2
- XKR4 | c.1299C>T p.F433= | Silent (SNP) | VAF 25/521 reads (5%) | catalogued as rs1280181269, COSV59304513, COSV59334659; called by muse, mutect2
- YTHDF1 | c.63T>C p.G21= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as COSV64834927; called by muse, mutect2, varscan2
- ZBTB12 | c.357C>T p.C119= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV64993826; called by muse, mutect2, varscan2
- ZBTB44 | c.708T>C p.I236= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV63538293; called by muse, mutect2, varscan2
- ZFHX3 | c.465C>T p.G155= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs774845273, COSV51732573; called by muse, mutect2, varscan2
- ZFPM2 | c.448C>T p.L150= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1206254121, COSV68291104; called by muse, mutect2, varscan2
- ZNF236 | c.762C>A p.A254= | Silent (SNP) | VAF 84/205 reads (41%) | catalogued as COSV53492666, COSV53496099; called by muse, mutect2, varscan2
- ZNF318 | c.5397C>G p.T1799= | Silent (SNP) | VAF 49/147 reads (33%) | catalogued as rs777642143, COSV58936695; called by muse, mutect2, varscan2
- ZNF586 | c.747T>C p.L249= | Silent (SNP) | VAF 59/162 reads (36%) | catalogued as COSV66972712; called by muse, mutect2, varscan2
- ZNF777 | c.1866G>A p.K622= | Silent (SNP) | VAF 70/208 reads (34%) | catalogued as COSV56099700; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849608 G>A | 5'Flank (SNP) | VAF 37/67 reads (55%) | catalogued as rs185167540; called by muse, mutect2, varscan2
- ALDH3A1 | chr17:19748379 C>T | 5'Flank (SNP) | VAF 19/68 reads (28%) | catalogued as rs765908428, COSV99855719, COSV99856043; called by muse, mutect2, varscan2
- ANKRD13D | c.*1128G>A | 3'UTR (SNP) | VAF 19/47 reads (40%) | catalogued as COSV57386442; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504791 C>A | 5'Flank (SNP) | VAF 33/104 reads (32%) | called by muse, mutect2, varscan2
- CFAP65 | c.542+91del | Intron (DEL) | VAF 17/40 reads (43%) | catalogued as rs572647237; called by mutect2, varscan2
- EVI2A | c.-11+565G>A | Intron (SNP) | VAF 10/140 reads (7%) | catalogued as COSV99907710; called by muse, mutect2
- GNAO1 | c.723+7057C>T | Intron (SNP) | VAF 24/75 reads (32%) | catalogued as rs199868005, COSV52619247; called by muse, mutect2, varscan2
- MTCL1 | c.2968-3209A>T | Intron (SNP) | VAF 76/212 reads (36%) | catalogued as COSV60410842; called by muse, mutect2, varscan2
- NVL | c.2183-6718del | Intron (DEL) | VAF 23/59 reads (39%) | catalogued as rs573934358; called by mutect2, varscan2
- PPP1R8 | c.*1164G>C | 3'UTR (SNP) | VAF 3/11 reads (27%) | catalogued as COSV99360981, COSV99361107; called by muse, mutect2
- PPP1R8 | c.*1165G>T | 3'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- PTPRN | c.2675+842A>G | Intron (SNP) | VAF 15/51 reads (29%) | catalogued as COSV55351644; called by muse, mutect2, varscan2
- RPGR | c.2520+1246del | Intron (DEL) | VAF 40/95 reads (42%) | called by mutect2, pindel, varscan2
- SSPOP | n.3226T>C | RNA (SNP) | VAF 4/14 reads (29%) | catalogued as COSV50489093; called by muse, mutect2, varscan2
